Somatic mutation profile of tumor specimen TARGET-10-PARETH-09A (aliquot TARGET-10-PARETH-09A-01D) from TARGET case TARGET-10-PARETH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,686 days).
Specimen TARGET-10-PARETH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3495f5e-9c94-440a-9349-9d06d52eb413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARETH-10A (Blood Derived Normal), aliquot TARGET-10-PARETH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2624e146-24e5-46dc-b311-4b727c56f7aa

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAND5 | c.384T>A p.H128Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); catalogued as COSV57683920; called by muse, mutect2, varscan2
- DCAF8L1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs146103278, COSV71595418; called by muse, mutect2, varscan2
- CASZ1 | c.4526C>T p.S1509L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM9A | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FES | c.32dup p.H13Pfs*29 | Frame Shift Ins (INS) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- PROSER1 | c.2492C>G p.A831G | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CASS4 | c.687C>T p.G229= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs769816537, COSV64389145; called by muse, mutect2, varscan2
- RNF111 | c.1887C>T p.P629= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as rs1232913485; called by muse, mutect2, varscan2
- ZNF366 | c.846G>A p.A282= | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as rs760974848, COSV59215328; called by muse, mutect2, varscan2
- COL1A1 | c.3261+20C>G | Intron (SNP) | VAF 32/138 reads (23%) | catalogued as COSV56804793; called by muse, mutect2
- KCNT2 | c.95+25753A>G | Intron (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
